Gene-level copy-number profile of tumor specimen ALCH-B2SK-TTP1-A from ALCHEMIST case ALCH-B2SK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.8 years (24,774 days).
Specimen ALCH-B2SK-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5d580d0d-3456-4481-9838-37e320ffbf2e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2SK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/cfa3c69c-9471-4232-bed5-d8857a38755a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 842; copy number 2: 23,405; copy number 3: 14,895; copy number 4: 10,334; copy number 5: 3,833; copy number 6: 2,193; copy number 7: 1,139; copy number 8: 628; copy number 9: 733; copy number 10: 52; copy number 11: 32; copy number 12: 62; copy number 13: 63; copy number 14: 119; copy number 15: 2; copy number 17: 1; copy number 19: 4; copy number 22: 10; copy number 40: 3.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr9:61,190,003–61,666,386, 12 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr15:22,056,709–22,057,638, 1 gene (within-gene range 0–5): OR4H6P.
- chr15:22,094,522–22,095,472, 1 gene (within-gene range 0–5): OR4N4.
- chr15:22,225,278–22,282,872, 3 genes: MIR1268A, AC025884.2, AC025884.1.
- chr15:93,718,542–94,600,821, 14 genes (within-gene range 0–3): LINC01579, AC103996.1, LINC02207, AC103996.3, AC103996.2, LINC01580, LINC01581, AC104390.1, H3P40, MCTP2, AC135626.1, AC135626.2, AC009432.2, AC009432.1.
- chr15:94,855,586–94,857,011, 1 gene (within-gene range 0–3): AC107976.1.
- chr16:85,963,328–85,985,386, 2 genes: AC092723.4, AC092723.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,869 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,512,653–8,513,021, 1 gene, copy number 5 (within-gene range 3–5): AL096855.2.
- chr1:28,668,778–28,719,353, 2 genes, copy number 5: GMEB1, AL645729.1.
- chr1:32,600,172–59,296,491, 703 genes, copy number 6–9 (within-gene range 3–9) (broad region; genes not listed).
- chr1:60,515,716–61,462,788, 5 genes, copy number 6: LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1.
- chr1:167,052,551–173,786,692, 150 genes, copy number 6 (broad region; genes not listed).
- chr1:178,542,752–186,988,981, 169 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:187,563,061–190,801,658, 29 genes, copy number 5: FDPSP1, AL357559.1, SLC4A1APP2, AL645474.1, AL136372.2, AL136372.1, RN7SKP156, AL596211.1, AL592447.1, AL929288.1, AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75, RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2.
- chr1:196,044,883–200,860,704, 65 genes, copy number 5 (broad region; genes not listed).
- chr1:222,010,825–242,773,103, 444 genes, copy number 5–7 (broad region; genes not listed).
- chr1:243,124,428–243,851,079, 10 genes, copy number 5 (within-gene range 4–5): CEP170, AL606534.1, AL606534.2, SDCCAG8, FCF1P7, MIR4677, AKT3, AL591721.1, FABP7P1, AL662889.1.
- chr2:17,385,091–17,817,798, 6 genes, copy number 10: PSMC1P10, RAD51AP2, VSNL1, SMC6, GEN1, MSGN1.
- chr2:20,859,771–21,970,959, 13 genes, copy number 6 (within-gene range 3–6): LINC02850, AC115619.1, APOB, AC010872.1, TDRD15, AC067959.1, AC018742.1, AC011752.1, NUTF2P8, AC009411.2, AC009411.1, LINC01822, RN7SL117P.
- chr2:41,819,747–70,125,317, 474 genes, copy number 5 (broad region; genes not listed).
- chr3:101,324,205–115,147,288, 194 genes, copy number 5–12 (within-gene range 3–12) (broad region; genes not listed).
- chr3:161,324,913–198,123,232, 639 genes, copy number 6 (broad region; genes not listed).
- chr4:932,387–2,462,942, 50 genes, copy number 5 (within-gene range 3–5): TMEM175, DGKQ, SLC26A1, IDUA, FGFRL1, AC019103.1, RNF212, AC092535.3, AC092535.4, TMED11P, AC092535.1, AC092535.2, SPON2, AC092535.5, CTBP1-AS, CTBP1, CTBP1-DT, MAEA, UVSSA, AC078852.2, AC078852.1, NKX1-1, AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L, POLN, HAUS3, AL136360.1, AL136360.2, COX6B1P5, MXD4, MIR4800, ZFYVE28, AL158068.2, RN7SL589P, AL158068.1, CFAP99.
- chr5:58,198–45,895,970, 679 genes, copy number 8–9 (broad region; genes not listed).
- chr6:18,223,860–25,057,073, 82 genes, copy number 5 (broad region; genes not listed).
- chr6:25,061,796–25,273,751, 8 genes, copy number 5: AL133268.4, AL133268.1, AL590084.3, AL590084.1, AL590084.2, KATNBL1P5, AL024509.2, AL024509.1.
- chr6:39,299,001–58,438,364, 363 genes, copy number 5–7 (broad region; genes not listed).
- chr6:126,304,223–127,213,609, 1 gene, copy number 5 (within-gene range 3–5): AL356534.1.
- chr6:126,590,287–132,868,859, 99 genes, copy number 5 (broad region; genes not listed).
- chr6:140,845,958–140,922,910, 2 genes, copy number 6: AL035446.1, AL357084.1.
- chr7:52,891,837–57,837,046, 157 genes, copy number 9–13 (broad region; genes not listed).
- chr7:63,087,070–95,296,415, 586 genes, copy number 5–14 (broad region; genes not listed).
- chr7:115,935,148–117,874,139, 49 genes, copy number 5: TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2.
- chr8:36,784,324–43,220,809, 154 genes, copy number 5–14 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,494 genes, copy number 5–7 (broad region; genes not listed).
- chr11:123,358,428–124,936,412, 76 genes, copy number 9–17 (broad region; genes not listed).
- chr12:12,310–34,249,958, 834 genes, copy number 6–11 (broad region; genes not listed).
- chr15:20,516,252–22,095,857, 81 genes, copy number 5–15 (within-gene range 0–15) (broad region; genes not listed).
- chr15:22,070,241–22,083,221, 1 gene, copy number 5: OR4M2.
- chr15:22,125,511–22,126,434, 1 gene, copy number 8 (within-gene range 5–8): OR4N3P.
- chr15:22,360,639–32,745,106, 339 genes, copy number 6 (broad region; genes not listed).
- chr17:71,097,774–71,202,203, 1 gene, copy number 6: CASC17.
- chr17:73,334,384–83,240,804, 428 genes, copy number 5 (broad region; genes not listed).
- chr18:721,588–812,546, 1 gene, copy number 40 (within-gene range 2–40): YES1.
- chr18:797,989–15,122,767, 333 genes, copy number 5–40 (broad region; genes not listed).
- chr19:18,572,220–18,621,039, 3 genes, copy number 6 (within-gene range 2–6): CRLF1, REX1BD, TMEM59L.
- chr20:61,252,261–64,327,972, 142 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 106. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
